Somatic mutation profile of tumor specimen TCGA-CM-5860-01A (aliquot TCGA-CM-5860-01A-01D-1650-10) from TCGA case TCGA-CM-5860, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 44.7 years (16,344 days).
Specimen TCGA-CM-5860-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45bad2f0-4951-423b-b0b3-1edb3e8b3418.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5860-10A (Blood Derived Normal), aliquot TCGA-CM-5860-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ae4fd1e-3a94-403f-a552-3560493079c6

The open-access MAF lists 121 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 31, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 4, Splice Region 3, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 96/418 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 63/106 reads (59%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- TRPV4 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs77975504, CM091510, COSV55680868; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL6B | c.1200+1G>A p.X400_splice | Splice Site (SNP) | VAF 75/162 reads (46%) | catalogued as COSV50513998; called by muse, mutect2, varscan2
- ADGRG5 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs777835722, COSV61082756; called by muse, mutect2, varscan2
- ARHGAP30 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1284488498, COSV63515243; called by muse, mutect2, varscan2
- ASXL1 | c.4328A>G p.K1443R | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60104655; called by muse, mutect2, varscan2
- ATP1A1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759607882, COSV99814549; called by muse, varscan2
- ATP8B3 | c.819C>T p.D273= | Splice Region (SNP) | VAF 53/181 reads (29%) | catalogued as rs754544405, COSV59540917; called by muse, mutect2, varscan2
- BPIFA1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs765317724, COSV62824032; called by muse, mutect2, varscan2
- C1RL | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56923837; called by mutect2, varscan2
- CCDC17 | c.1748C>T p.T583I | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs538598010, COSV59646104; called by muse, mutect2, varscan2
- CCKBR | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV58099380; called by muse, mutect2, varscan2
- CDK5 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52528032; called by muse, mutect2, varscan2
- CEACAM16 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs544948409, COSV69186362; called by muse, mutect2, varscan2
- CES3 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.173); catalogued as COSV100309957; called by muse, mutect2
- CNGB3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs777404947, COSV60686170; called by muse, mutect2, varscan2
- COL11A1 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759469788, COSV62175625; called by muse, mutect2, varscan2
- COL4A5 | c.3515A>T p.D1172V | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100088028; called by muse, mutect2
- CROCC | c.3445C>T p.R1149W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs374075325; called by muse, mutect2, varscan2
- DHX9 | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62360747; called by muse, mutect2, varscan2
- DLG2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs199599488; called by muse, mutect2, varscan2
- DRG2 | c.540G>A p.K180= | Splice Region (SNP) | VAF 48/95 reads (51%) | catalogued as COSV56727853; called by muse, mutect2, varscan2
- DSP | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs756671027, COSV65791691; called by muse, mutect2, varscan2
- ELFN2 | c.1471C>A p.L491M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs776247026, COSV68744049; called by muse, mutect2, varscan2
- ENOX2 | c.848G>A p.R283H (on ENST00000338144 / NM_001382520.1; = p.R254H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1177230131, COSV100583749; called by muse, mutect2
- EPHB4 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774048106, COSV100639524; called by muse, mutect2, varscan2
- FAM47A | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV60494861; called by muse, mutect2, varscan2
- FAT3 | c.13564G>A p.G4522S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as rs200062618; called by muse, mutect2, varscan2
- FRMD3 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV58456301; called by muse, mutect2
- FSTL4 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV54765877; called by muse, mutect2, varscan2
- GPC4 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV63697210; called by muse, mutect2, varscan2
- IL4R | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as rs1315085904, COSV99405101; called by muse, mutect2, varscan2
- JAKMIP1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs371853673, COSV51537918; called by muse, mutect2, varscan2
- KCNA5 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417908904, COSV52903705, COSV99363617; called by muse, mutect2, varscan2
- KIAA1109 | c.14438C>G p.P4813R | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52665132; called by muse, mutect2
- KLHL22 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs760729910, COSV100186189, COSV61020087; called by muse, mutect2, varscan2
- LHCGR | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV54293894; called by muse, varscan2
- LINS1 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV59078163; called by muse, mutect2, varscan2
- LRRC8C | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747378312, COSV64996016; called by muse, mutect2, varscan2
- LRRIQ1 | c.4115C>A p.S1372Y | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs747439668, COSV67827148, COSV67834565; called by muse, mutect2, varscan2
- MGP | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as rs753350275, COSV57454123; called by muse, mutect2, varscan2
- MMP16 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 105/351 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs202054317, COSV54154850; called by muse, mutect2, varscan2
- MMP16 | c.282-1G>A p.X94_splice | Splice Site (SNP) | VAF 59/96 reads (61%) | catalogued as COSV54154856; called by mutect2, varscan2
- MON1A | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1186165540, COSV56559664; called by muse, mutect2, varscan2
- NBEA | c.8267G>A p.R2756Q | Missense Mutation (SNP) | VAF 35/411 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs1360065637, COSV59766932; called by muse, mutect2
- NDUFS5 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 112/254 reads (44%) | catalogued as rs751638359, COSV65892280, COSV65892504; called by muse, varscan2
- NLRC3 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs373378033; called by muse, mutect2, varscan2
- ODF2L | c.1624G>A p.A542T (on ENST00000317336; = p.A526T on NM_020729.3) | Missense Mutation (SNP) | VAF 114/708 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs370305366; called by muse, mutect2, varscan2
- ODF3B | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV52686823; called by muse, mutect2, varscan2
- OR52K2 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV57834749; called by muse, mutect2, varscan2
- OR5H6 | c.886G>A p.V296I (on ENST00000642105; = p.V280I on NM_001005479.2) | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.116); catalogued as rs1307264550, COSV67351160; called by muse, mutect2, varscan2
- PDILT | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56700280; called by muse, varscan2
- PSD | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV50042517; called by muse, mutect2, varscan2
- PTPRC | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as COSV61408016; called by muse, mutect2, varscan2
- REV1 | c.3639G>C p.M1213I | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV99177305; called by muse, mutect2
- RNF31 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs781285193, COSV60725908; called by muse, mutect2, varscan2
- RPL28 | c.40T>C p.S14P | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV59804458; called by muse, mutect2, varscan2
- SGTB | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51556735; called by muse, mutect2, varscan2
- SHANK2 | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781922255, COSV53587768; called by muse, mutect2, varscan2
- SHB | c.1055-2A>G p.X352_splice | Splice Site (SNP) | VAF 43/83 reads (52%) | catalogued as COSV66628640; called by muse, mutect2, varscan2
- SLC1A6 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs779014705, COSV55668002; called by muse, mutect2, varscan2
- SLIT1 | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs546232285, COSV56584537; called by muse, mutect2, varscan2
- SS18L1 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV59208743, COSV59209473; called by muse, mutect2, varscan2
- STRC | c.3718G>T p.A1240S | Missense Mutation (SNP) | VAF 183/462 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as COSV68659570; called by muse, mutect2, varscan2
- SYNE1 | c.20032C>A p.H6678N (on ENST00000367255 / NM_182961.4; = p.H6607N on NM_033071.3) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99567277, COSV99585724; called by muse, mutect2, varscan2
- SYPL2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1252252309, COSV63994739, COSV63994800; called by muse, mutect2, varscan2
- TAFA5 | c.199C>T p.R67C (on ENST00000402357 / NM_001082967.3; = p.R60C on NM_015381.7) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606283, COSV60972277; called by muse, mutect2, varscan2
- TICAM1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV50229952; called by muse, mutect2, varscan2
- TLK1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1317989051, COSV100687965; called by muse, mutect2, varscan2
- TMTC1 | c.1156G>A p.G386S (on ENST00000539277 / NM_001193451.2; = p.G278S on NM_175861.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs910785203, COSV55477210; called by muse, mutect2, varscan2
- TRAF3IP3 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs755111399, COSV50550896; called by muse, mutect2, varscan2
- TRPS1 | c.2886G>T p.Q962H (on ENST00000220888 / NM_001330599.2; = p.Q975H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/534 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV55230171; called by muse, mutect2, varscan2
- TRRAP | c.10266G>A p.T3422= (on ENST00000359863 / NM_001244580.1; = p.T3393= on NM_003496.3) | Splice Region (SNP) | VAF 76/143 reads (53%) | catalogued as rs368847796; called by muse, mutect2, varscan2
- TUT1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765502633, COSV53469112, COSV99545558; called by muse, mutect2, varscan2
- USP5 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV57531053; called by muse, mutect2, varscan2
- WIPF1 | c.1457-1G>A p.X486_splice | Splice Site (SNP) | VAF 67/165 reads (41%) | catalogued as COSV55812233, COSV99769165; called by muse, mutect2, varscan2
- ZFHX4 | c.7373T>G p.L2458R | Missense Mutation (SNP) | VAF 86/142 reads (61%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.165); catalogued as COSV50589877, COSV51476909; called by muse, mutect2
- ZKSCAN5 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV58742165; called by muse, mutect2, varscan2
- ZNF341 | c.2033C>T p.S678F (on ENST00000375200 / NM_001282935.1; = p.S671F on NM_032819.4) | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61006921; called by muse, mutect2, varscan2
- ZNF347 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61967834; called by muse, mutect2, varscan2
- ZNFX1 | c.2506C>G p.R836G | Missense Mutation (SNP) | VAF 270/642 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871062, COSV65574197; called by muse, mutect2, varscan2
- LTBP4 | c.575del p.P192Rfs*29 (on ENST00000308370 / NM_001042544.1; = p.P155Rfs*29 on NM_003573.2) | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- MARCHF4 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- NKRF | c.1373_1374del p.T458Sfs*4 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | called by pindel, varscan2
- POLR1A | c.824_827del p.F275* | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by pindel, varscan2
- SPCS3 | c.259_262del p.L87Ifs*13 | Frame Shift Del (DEL) | VAF 99/269 reads (37%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.690G>A p.P230= | Silent (SNP) | VAF 93/119 reads (78%) | catalogued as COSV52264815; called by muse, mutect2, varscan2
- CADM2 | c.1159C>T p.L387= (on ENST00000407528 / NM_001167674.2; = p.L389= on NM_153184.4) | Silent (SNP) | VAF 22/356 reads (6%) | catalogued as COSV101056526; called by muse, mutect2
- CNTN6 | c.2340G>T p.V780= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as COSV63164845; called by muse, mutect2, varscan2
- CSMD3 | c.3234C>A p.I1078= (on ENST00000297405 / NM_001363185.1; = p.I974= on NM_052900.3) | Silent (SNP) | VAF 71/122 reads (58%) | catalogued as COSV52124854, COSV99842025; called by muse, mutect2, varscan2
- EIF2D | c.1497G>A p.A499= | Silent (SNP) | VAF 51/244 reads (21%) | catalogued as rs202132052, COSV55112581; called by muse, mutect2, varscan2
- EPB41L3 | c.2925G>T p.V975= | Silent (SNP) | VAF 128/224 reads (57%) | catalogued as COSV100549439; called by muse, mutect2, varscan2
- EPG5 | c.1752T>C p.F584= | Silent (SNP) | VAF 47/76 reads (62%) | catalogued as COSV56346054; called by muse, mutect2, varscan2
- FAT3 | c.12375G>A p.T4125= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs1448341536, COSV53080896, COSV53085919; called by muse, mutect2, varscan2
- FBXO24 | c.1722G>T p.G574= (on ENST00000241071 / NM_033506.3; = p.G612= on NM_012172.5) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99575417; called by muse, mutect2, varscan2
- GLI3 | c.1059G>A p.A353= | Silent (SNP) | VAF 85/184 reads (46%) | catalogued as rs759502281, COSV67886141; called by muse, mutect2, varscan2
- GPM6A | c.174G>T p.L58= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as rs1235139694, COSV99704251; called by muse, mutect2, varscan2
- GPR45 | c.531G>A p.A177= | Silent (SNP) | VAF 56/82 reads (68%) | catalogued as COSV51523088; called by muse, mutect2, varscan2
- HDAC11 | c.291C>A p.P97= | Silent (SNP) | VAF 57/269 reads (21%) | catalogued as COSV55472501, COSV55472602; called by muse, mutect2, varscan2
- KIRREL3 | c.2067C>T p.Y689= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs376728531; called by muse, mutect2, varscan2
- LMTK3 | c.1332G>A p.P444= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1192334865, COSV54310442; called by muse, mutect2, varscan2
- MAGEC3 | c.9G>T p.L3= | Silent (SNP) | VAF 96/117 reads (82%) | catalogued as rs775946254, COSV53577158; called by muse, mutect2, varscan2
- MYO1H | c.2001A>G p.A667= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV60443626; called by muse, mutect2
- NECTIN1 | c.897C>T p.T299= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as COSV50598321; called by muse, mutect2, varscan2
- NPFFR2 | c.786G>A p.A262= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs916800338, COSV58147712; called by muse, mutect2, varscan2
- PADI4 | c.822G>A p.T274= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs148703657; called by muse, mutect2, varscan2
- PCDHA5 | c.1551C>T p.Y517= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs782587996, COSV65349128, COSV65350259; called by muse, mutect2, varscan2
- PGLYRP2 | c.156G>A p.A52= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs377757963; called by muse, mutect2, varscan2
- PSG4 | c.234C>T p.Y78= | Silent (SNP) | VAF 127/454 reads (28%) | catalogued as rs183355892, COSV99736394; called by muse, varscan2
- PTPRH | c.2466C>T p.D822= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs149252651; called by muse, mutect2, varscan2
- SLA2 | c.156G>A p.S52= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs372613643; called by muse, mutect2, varscan2
- SLC4A3 | c.868C>A p.R290= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV56092158; called by muse, mutect2, varscan2
- TJP1 | c.3135C>T p.Y1045= | Silent (SNP) | VAF 114/572 reads (20%) | catalogued as rs373853690; called by muse, varscan2
- TRANK1 | c.4941C>T p.I1647= | Silent (SNP) | VAF 33/367 reads (9%) | catalogued as COSV57143800; called by muse, mutect2
- TRAT1 | c.372C>T p.P124= | Silent (SNP) | VAF 65/275 reads (24%) | catalogued as COSV55467651; called by muse, mutect2, varscan2
- UBR4 | c.1683C>T p.S561= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs372095685; called by muse, mutect2, varscan2
- USH2A | c.12786T>C p.P4262= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV56338849; called by muse, mutect2, varscan2
- CARS1 | c.26-5630C>T | Intron (SNP) | VAF 14/78 reads (18%) | catalogued as rs754826357, COSV53451556; called by muse, mutect2, varscan2
- OPA1 | c.-1G>T | 5'UTR (SNP) | VAF 34/91 reads (37%) | catalogued as COSV100655356; called by muse, mutect2, varscan2
